Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A8HX, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A8HX-01A (Primary Tumor).

[page 1 of 5]
IRB APPROVED

Clinical Case Report (For Collection of Cancerous Tissue)

IAD-6-3
CKF
Carcinoma, urothelial cell
8/20/3
path NOS
Carcinoma, transitional cell
papillary 8/30/3
CKF
Site: Bladder NOS C67.9
path Bladder, overlapping lesion C67.8
9/11/26/11

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married ☐ Divorced ☐ Widow	VIETNAMESE	
☐ Male ☒ Female			Blood Pressure	Heart Rate
			121/7	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain ; fever ; blood in urine
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal	13 years old	02	
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☒ Post-menopausal	47 years old	02	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD		☐ Hormone Replacement Therapy: _____	
☐ Other: _____			

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers: _____						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumour was found in the U. bladder	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Urinary bladder cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T2 N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Resection of U bladder			
Primary Tumor			
Organ	Detailed Location		Size
Urinary bladder tumor	overlapping lesion		3 x 2 x 1 cm
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes		# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location		Size
Surgical Staging			
T 2 N 0 M 0			Stage: II

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by:

Date: _____ Time: _____

Preserved by:

Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
urinary bladder tumor	3 x 2 x 1 cm	overlapping	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 2 N 0 M 0		Stage: II	
Notes:			

[page 5 of 5]
IRB APPROVED

Consolidated Pathology Diagnosis

ID#: _____

Cell Distribution			Structural Pattern		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration	☒		Palisading		
Vascular Invasion		☒	Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File			Psammoma/Calcification		

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☐ Moderate ☐ Poor

Nuclear Atypia:

	0	I	II	III
Aniso Nucleosis				
Hyperchromatism		☒		
Nucleolar Prominent			☒	
Multinucleated Giant Cell		☒		
Mitotic Activity			☒	

Nuclear Grade: ☒ 0 ☐ I ☐ II ☐ III

D1 90% D2 70% D3 60% D4 80%

Final Pathology Report

Histological Diagnosis: capillary transitional cell carcinoma Grade: 2

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Diagnosis Consistency	☒	☐
IPSA Discrepancy	☒	☐
For Malignancy History	☒	☐
Qual/Synchronicity Primary Noted	☒	☐

Source: NCI Genomic Data Commons file c52fba3d-9744-4231-b2c9-1725f3fa4e1d (TCGA-CF-A8HX.347944A8-FA38-477F-B68C-5851B2097790.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).